Somatic mutation profile of tumor specimen TARGET-15-PARWPU-09A.3 (aliquot TARGET-15-PARWPU-09A.3-01D) from TARGET case TARGET-15-PARWPU, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,129 days).
Specimen TARGET-15-PARWPU-09A.3: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4db537fa-8bc7-47ee-b23c-4089098f8923.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-PARWPU-14A (Bone Marrow Normal), aliquot TARGET-15-PARWPU-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba0c3f9b-de0f-4d1a-b7ee-56c236669da3

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PHC2 | c.1902G>T p.E634D (on ENST00000257118 / NM_198040.2; = p.E99D on NM_004427.4) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.97); catalogued as rs1468794896, COSV99930785; called by muse, mutect2
- WNT3 | c.260G>T p.R87L | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56646704; called by muse, mutect2
- PATL1 | c.2274G>T p.L758F | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.399); called by muse, mutect2
- RIPOR2 | c.3007dup p.I1003Nfs*3 | Frame Shift Ins (INS) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- ZFYVE28 | c.2549G>T p.C850F | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CUTA | c.78G>T p.A26= (on ENST00000488034 / NM_001014840.2; = p.A3= on NM_015921.3) | Silent (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- ZNF76 | c.813C>A p.I271= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV57591480; called by muse, mutect2, varscan2
- AK9 | c.3633+13_3633+15del | Intron (DEL) | VAF 8/54 reads (15%) | catalogued as rs201441562; called by pindel, varscan2
